TARGET case TARGET-15-SJMPAL042941 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d5c97025-3f70-4ef7-9bc2-e8bc60359787

Demographics
Sex at birth: male; Age at index: 0 years; Vital status: Alive.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 0.4 years (140 days); Year of diagnosis: 2009.

Follow-up (1 entry)
- Follow-up contact recording only the day: follow-up.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day 0: Leukocytes 11.9 ×10³/µL.

Biospecimens (4 samples)
- Samples TARGET-15-SJMPAL042941-09A, TARGET-15-SJMPAL042941-09A.2 (2 with the same recorded description): Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-15-SJMPAL042941-09A.1: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample TARGET-15-SJMPAL042941-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_III_20230725.xlsx:
- Protocol: Westmead
- WBC at Diagnosis: 11.9
- Karyotype: 46,XY,t(9;11)(p22;q23)[20]
- WHO ALAL Classification: MLL
- WHO Dx: T/M
